TARGET case TARGET-30-PALFJL — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/dcb2640d-22e4-52a1-8d98-628e456fd575

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 2.3 years (829 days); Year of diagnosis: 2001; Days to last follow up: 1,228 days (3.4 years); INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PALFJL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
